Somatic mutation profile of tumor specimen TCGA-DD-AADF-01A (aliquot TCGA-DD-AADF-01A-11D-A40R-10) from TCGA case TCGA-DD-AADF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 64.7 years (23,614 days).
Specimen TCGA-DD-AADF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c785a3fe-2451-47a8-92fb-8e612d1d656e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADF-10A (Blood Derived Normal), aliquot TCGA-DD-AADF-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55c138bd-f160-471f-b33c-0fa4a949a1e1

The open-access MAF lists 236 somatic variants for this specimen: 186 protein-altering or splice-affecting, 46 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 46, Frame Shift Del 8, Nonsense Mutation 8, Splice Region 5, Splice Site 2, Intron 2, Translation Start Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.262G>T p.A88S (on ENST00000502732 / NM_007314.4; = p.A73S on NM_005158.5) | Missense Mutation (SNP) | VAF 118/194 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV100773102, COSV61012148; called by muse, mutect2, varscan2
- ADAMTS7 | c.1847T>A p.L616Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV101183304; called by muse, mutect2, varscan2
- ADAT1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100329330; called by muse, mutect2, varscan2
- ALDOB | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100878944; called by muse, mutect2, varscan2
- ANXA13 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs531775603, COSV99147221; called by muse, mutect2, varscan2
- AP5M1 | c.416A>C p.Q139P | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV99841402; called by muse, mutect2, varscan2
- APEX2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV100895222; called by muse, mutect2, varscan2
- ARFGAP1 | c.1052G>A p.C351Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV100796743; called by muse, mutect2, varscan2
- ARHGAP36 | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as COSV99358307; called by muse, mutect2, varscan2
- ARHGEF19 | c.1090A>T p.S364C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99580848; called by muse, mutect2, varscan2
- ARPP21 | c.1445T>A p.L482H | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99493634; called by muse, mutect2, varscan2
- ASCC3 | c.4990G>T p.G1664* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100977017; called by muse, mutect2, varscan2
- ASCC3 | c.4989G>T p.K1663N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100977020; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- CAMTA1 | c.800G>C p.S267T | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs761165547, COSV100352647; called by muse, mutect2, varscan2
- CCDC3 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101121771, COSV66558838; called by muse, mutect2, varscan2
- CCDC30 | c.480T>A p.C160* (on ENST00000340612; = p.C117* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 31/401 reads (8%) | catalogued as COSV100501748; called by muse, mutect2
- CD86 | c.53T>A p.F18Y (on ENST00000330540 / NM_175862.5; = p.F12Y on NM_006889.4) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV100054248, COSV52605388; called by muse, mutect2, varscan2
- CDC42BPA | c.4626del p.R1543Vfs*24 (on ENST00000334218 / NM_001366019.2; = p.R1530Vfs*24 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as COSV62023387; called by mutect2, pindel, varscan2
- CDHR4 | c.113A>C p.Q38P | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.188); catalogued as COSV100323782; called by muse, mutect2, varscan2
- CHD5 | c.203A>T p.K68I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV99315369; called by muse, mutect2, varscan2
- CHST13 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV100081415; called by muse, mutect2, varscan2
- CNGA3 | c.1787A>T p.K596M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV99737640; called by muse, mutect2, varscan2
- CNTNAP5 | c.1699A>C p.T567P | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV101444325; called by muse, mutect2, varscan2
- COBLL1 | c.3316T>G p.F1106V (on ENST00000392717; = p.F1068V on NM_014900.5) | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV99528817; called by muse, mutect2, varscan2
- COL11A1 | c.2737G>T p.G913C | Missense Mutation (SNP) | VAF 103/183 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618226; called by muse, mutect2, varscan2
- COL12A1 | c.8810G>T p.S2937I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as COSV59394674; called by muse, mutect2, varscan2
- DBNL | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101289388; called by muse, mutect2, varscan2
- DDIT4L | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99914000; called by muse, mutect2, varscan2
- DHX37 | c.3001G>A p.V1001I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1220648222, COSV100439573; called by muse, mutect2, varscan2
- DIPK2A | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100237511; called by muse, mutect2, varscan2
- DIPK2A | c.1026C>G p.C342W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100237514; called by muse, mutect2, varscan2
- DLG5 | c.5575G>A p.D1859N | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100967955; called by muse, mutect2, varscan2
- DNAH2 | c.1399C>A p.L467M | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV99318637; called by muse, mutect2, varscan2
- DOC2A | c.781T>A p.Y261N | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451423; called by muse, mutect2, varscan2
- DYNC2H1 | c.12692A>T p.Q4231L | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100519945; called by muse, mutect2, varscan2
- EML4 | c.2374A>T p.I792F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100581481; called by muse, mutect2, varscan2
- EPB41L4B | c.1547A>G p.H516R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1045638372, COSV101000962; called by muse, mutect2, varscan2
- EPHA2 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV100626342; called by muse, mutect2, varscan2
- ERC1 | c.3194A>T p.Q1065L (on ENST00000360905 / NM_178040.4; = p.Q1037L on NM_178039.4) | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100706871; called by muse, mutect2, varscan2
- EVC2 | c.3764T>A p.V1255E | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as COSV100187107; called by muse, mutect2, varscan2
- EYS | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs149421359; called by muse, mutect2, varscan2
- FBXL17 | c.1806T>A p.C602* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100672977; called by muse, mutect2, varscan2
- FBXW12 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV56482634, COSV99601871; called by muse, mutect2
- FER1L6 | c.2999G>T p.G1000V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373037712; called by muse, mutect2, varscan2
- FLNA | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs868971677, COSV100775342; called by muse, mutect2, varscan2
- FLNB | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99915306; called by muse, mutect2, varscan2
- FOCAD | c.3465A>T p.Q1155H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100620748, COSV58107724; called by muse, mutect2, varscan2
- FRAS1 | c.11702A>T p.Q3901L | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV99356347; called by muse, mutect2, varscan2
- FRG2 | c.400A>C p.N134H | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV66460488; called by muse, mutect2, varscan2
- FRMPD3 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99347236; called by muse, mutect2, varscan2
- FSHR | c.1144A>T p.I382L | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV58638526; called by muse, mutect2
- FYB1 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 52/127 reads (41%) | catalogued as COSV100686552; called by muse, mutect2, varscan2
- GABRG1 | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 102/409 reads (25%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.911); catalogued as COSV99778858; called by muse, mutect2
- GABRP | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as rs79061387, COSV99517163; called by muse, mutect2, varscan2
- GPR3 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as COSV100927553; called by muse, mutect2, varscan2
- GPRIN1 | c.1898A>T p.Q633L | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99992263; called by muse, mutect2, varscan2
- HFM1 | c.1376C>G p.T459R | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646980; called by muse, mutect2, varscan2
- HMCN1 | c.5162A>T p.K1721M | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV99637059; called by muse, mutect2, varscan2
- HNRNPF | c.6G>T p.M2I | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV100563360; called by muse, mutect2, varscan2
- HSF1 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 111/190 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101275174; called by muse, mutect2, varscan2
- IGHE | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as rs782435085; called by muse, mutect2
- IL17A | c.272A>T p.E91V | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100391703; called by muse, mutect2, varscan2
- IQCA1 | c.1537A>T p.K513* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99610527; called by muse, mutect2, varscan2
- IQSEC1 | c.2168A>T p.Q723L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV99832504; called by muse, mutect2, varscan2
- IQSEC2 | c.1951C>A p.P651T (on ENST00000642864 / NM_001111125.3; = p.P446T on NM_015075.2) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.801); catalogued as COSV100945123, COSV64727447; called by muse, mutect2, varscan2
- ITGAD | c.2604T>A p.H868Q | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV101210610; called by muse, mutect2, varscan2
- JADE3 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99510425; called by muse, mutect2
- JAG2 | c.3413T>C p.I1138T | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1292064765, COSV100078895; called by muse, mutect2, varscan2
- KCNH4 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99238010; called by muse, mutect2, varscan2
- KCNK3 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257253; called by muse, mutect2, varscan2
- KCNMB2 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV100844063; called by muse, mutect2, varscan2
- KCNQ2 | c.2303A>T p.Q768L (on ENST00000359125 / NM_172107.4; = p.Q740L on NM_004518.6) | Missense Mutation (SNP) | VAF 101/180 reads (56%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100610639; called by muse, mutect2, varscan2
- KCNT1 | c.1780C>G p.R594G (on ENST00000488444; = p.R613G on NM_020822.3) | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99706900; called by muse, mutect2, varscan2
- KEL | c.1946A>G p.Y649C | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100787336; called by muse, mutect2, varscan2
- KIAA1841 | c.1546A>T p.I516L | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs771992978, COSV99694282; called by muse, mutect2, varscan2
- KLHL38 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559948746, COSV100384644; called by muse, mutect2
- KMT2D | c.16185G>T p.W5395C | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99986390; called by muse, mutect2, varscan2
- KNDC1 | c.3556A>T p.S1186C | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV100466475; called by muse, mutect2, varscan2
- KRT1 | c.1819G>C p.G607R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs1420204921, COSV99359028; called by muse, mutect2, varscan2
- KRT12 | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs377161982, COSV99289166; called by muse, mutect2, varscan2
- KTN1 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100783290; called by muse, mutect2, varscan2
- LAMA3 | c.5465G>A p.C1822Y (on ENST00000313654 / NM_198129.4; = p.C213Y on NM_000227.6) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335978; called by muse, mutect2, varscan2
- LAMB1 | c.410T>G p.I137R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99741840; called by muse, mutect2, varscan2
- LGALS12 | c.799-2A>T p.X267_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99737410; called by muse, mutect2, varscan2
- LORICRIN | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | PolyPhen benign (0); catalogued as COSV100907308; called by muse, varscan2
- LOX | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99140746; called by muse, mutect2, varscan2
- LRCH2 | c.997A>T p.S333C | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.99); catalogued as COSV100407710; called by muse, mutect2, varscan2
- LRRC14B | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99361244; called by muse, mutect2, varscan2
- LRRC24 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs759034057, COSV99468367; called by muse, mutect2, varscan2
- MAP1B | c.7259T>A p.L2420Q | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99703020; called by muse, mutect2, varscan2
- MAP3K20 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/85 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100169594; called by muse, mutect2, varscan2
- MAST4 | c.2294A>G p.D765G (on ENST00000403625 / NM_001164664.2; = p.D576G on NM_015183.3) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846244; called by muse, mutect2, varscan2
- MAST4 | c.7116G>T p.K2372N (on ENST00000403625 / NM_001164664.2; = p.K2183N on NM_015183.3) | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.152); catalogued as COSV99846249; called by muse, mutect2, varscan2
- MBOAT1 | c.474T>C p.D158= | Splice Region (SNP) | VAF 18/66 reads (27%) | catalogued as rs774806715, COSV100209315; called by muse, mutect2, varscan2
- MCTP1 | c.1070A>T p.D357V | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs777016909, COSV100388402; called by muse, mutect2, varscan2
- MED12 | c.4807C>A p.Q1603K | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.379); catalogued as COSV100380290; called by muse, mutect2, varscan2
- MEP1A | c.1934A>T p.Q645L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV100042294; called by muse, mutect2, varscan2
- MINDY3 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV99511060; called by muse, mutect2, varscan2
- MROH5 | c.829T>A p.W277R | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101436186; called by muse, mutect2, varscan2
- MSLNL | c.918C>A p.G306= | Splice Region (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99558880; called by muse, mutect2, varscan2
- MUC16 | c.4636A>T p.S1546C | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV101202023; called by muse, mutect2, varscan2
- MUC17 | c.1708A>T p.T570S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs748611024, COSV100075411; called by muse, mutect2
- MUSK | c.562T>G p.Y188D | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505270; called by muse, mutect2, varscan2
- MUSK | c.563A>T p.Y188F | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505273; called by muse, mutect2, varscan2
- MYH4 | c.5437A>C p.K1813Q | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99702449; called by muse, mutect2, varscan2
- MYOCD | c.39G>T p.R13S | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100591536; called by muse, mutect2, varscan2
- NAA15 | c.536A>T p.Q179L | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV99649988; called by muse, mutect2, varscan2
- NEB | c.7876A>G p.N2626D | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV99428689; called by muse, mutect2, varscan2
- NEUROG2 | c.625T>G p.S209A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV100511969; called by muse, mutect2, varscan2
- NIN | c.3401A>T p.Q1134L | Missense Mutation (SNP) | VAF 63/76 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV99815627; called by muse, mutect2, varscan2
- NMS | c.341C>A p.S114* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100966676; called by muse, mutect2, varscan2
- NPM2 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99235833; called by muse, mutect2, varscan2
- NTN4 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100643890; called by muse, mutect2, varscan2
- NUDT10 | c.*2G>A | Splice Region (SNP) | VAF 114/399 reads (29%) | catalogued as COSV100726812, COSV100726859; called by muse, mutect2, varscan2
- OPRM1 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002637; called by muse, mutect2, varscan2
- OR5K1 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 51/93 reads (55%) | catalogued as COSV100221052, COSV60304383; called by muse, mutect2, varscan2
- OR5R1 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.242); catalogued as COSV56571530; called by muse, mutect2, varscan2
- OR6C65 | c.765T>A p.F255L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101110215; called by muse, varscan2
- OR6M1 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100484211; called by muse, mutect2, varscan2
- PCDHA13 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV99170121; called by muse, mutect2, varscan2
- PCDHGA5 | c.571T>A p.Y191N | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.02); catalogued as COSV99548636; called by muse, mutect2
- PCSK9 | c.1680A>T p.T560= | Splice Region (SNP) | VAF 63/123 reads (51%) | catalogued as COSV100135618; called by muse, mutect2, varscan2
- PHF8 | c.2213G>C p.G738A (on ENST00000357988 / NM_001184896.1; = p.G702A on NM_015107.3) | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.132); catalogued as COSV100155009; called by muse, varscan2
- PHLPP1 | c.3784G>A p.G1262S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759420494, COSV99409472; called by muse, mutect2, varscan2
- PIGM | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs751223203, COSV100928077; called by muse, mutect2, varscan2
- PLA2G4F | c.662T>A p.L221Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV101215445; called by muse, mutect2, varscan2
- PLEKHA7 | c.2609C>A p.T870N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100262037, COSV60580203; called by muse, mutect2, varscan2
- PLXNA3 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100860298; called by muse, mutect2, varscan2
- POGZ | c.2711T>C p.L904S | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99305348; called by muse, mutect2, varscan2
- PPP1R17 | c.81A>T p.L27F | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV100566505; called by muse, mutect2, varscan2
- PRELID2 | c.247A>T p.S83C (on ENST00000334744 / NM_182960.4; = p.S42C on NM_138492.6) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100597320; called by muse, mutect2, varscan2
- PREX1 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs780805102, COSV100906880; called by muse, mutect2, varscan2
- PRUNE2 | c.2801T>A p.L934Q | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100945250; called by muse, mutect2, varscan2
- PTPN6 | c.797A>T p.Q266L | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100017326; called by muse, mutect2, varscan2
- PTTG2 | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 82/132 reads (62%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.789); catalogued as COSV99792386; called by muse, mutect2, varscan2
- QRICH2 | c.1832A>G p.D611G | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99429821; called by muse, mutect2
- RAC3 | c.433A>T p.M145L | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV100141982; called by muse, mutect2
- RGMA | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201783150, COSV100224759; called by muse, mutect2, varscan2
- RNASE3 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as rs183860442, COSV58959404; called by muse, mutect2, varscan2
- RTTN | c.6598C>A p.P2200T (on ENST00000255674; = p.L2222= on NM_173630.4) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV99734024; called by muse, mutect2, varscan2
- RYR2 | c.11111A>T p.D3704V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV63693069; called by muse, mutect2, varscan2
- SACS | c.8443C>A p.L2815I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV101207790; called by muse, mutect2, varscan2
- SCARF2 | c.1232A>T p.H411L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99839498; called by muse, mutect2, varscan2
- SCCPDH | c.814-2A>T p.X272_splice | Splice Site (SNP) | VAF 56/87 reads (64%) | catalogued as COSV100829750; called by muse, mutect2, varscan2
- SELPLG | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as COSV99947764; called by muse, mutect2, varscan2
- SERBP1 | c.781G>T p.G261C (on ENST00000370995 / NM_001018067.2; = p.G240C on NM_015640.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100769190; called by muse, mutect2, varscan2
- SERPINB13 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99501320; called by muse, mutect2, varscan2
- SLC12A7 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99370700; called by muse, mutect2, varscan2
- SLC25A48 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); catalogued as rs763713066, COSV99192265; called by muse, mutect2, varscan2
- SLC9A4 | c.2002T>A p.S668T | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99763654; called by muse, mutect2, varscan2
- SOCS2 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV100500111; called by muse, mutect2, varscan2
- SORL1 | c.4676A>T p.Q1559L | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99495735; called by muse, mutect2, varscan2
- SPATA18 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99731407; called by muse, mutect2, varscan2
- SPATA31D1 | c.961T>A p.L321M | Missense Mutation (SNP) | VAF 95/137 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100783106, COSV61197902; called by muse, mutect2, varscan2
- STX5 | c.906G>A p.Q302= | Splice Region (SNP) | VAF 41/109 reads (38%) | catalogued as COSV99587116; called by muse, mutect2, varscan2
- SWT1 | c.1697A>T p.K566M | Missense Mutation (SNP) | VAF 136/501 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100833571; called by muse, mutect2, varscan2
- SYNM | c.3452A>T p.E1151V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100019379; called by muse, mutect2, varscan2
- TANC1 | c.4922C>T p.A1641V | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99714107; called by muse, mutect2, varscan2
- TBL1X | c.1256A>G p.K419R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as COSV99483259; called by muse, mutect2, varscan2
- TBXT | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99753003; called by muse, mutect2, varscan2
- TENM1 | c.6536A>G p.N2179S | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100951188; called by muse, mutect2, varscan2
- TFCP2L1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99748892; called by muse, mutect2, varscan2
- THBS3 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs143240289, COSV100366985; called by muse, mutect2, varscan2
- TMEM144 | c.718T>A p.F240I | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV99647046; called by muse, mutect2, varscan2
- TMEM208 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.193); catalogued as COSV99264596; called by muse, varscan2
- TMF1 | c.2189A>T p.Q730L | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV101275475; called by muse, mutect2, varscan2
- TRIM47 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as rs748897915, COSV99638708; called by muse, mutect2
- TRPC7 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100726081; called by muse, mutect2, varscan2
- TTC22 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100988190; called by muse, mutect2, varscan2
- TUBB6 | c.218T>A p.M73K | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100481236; called by muse, mutect2, varscan2
- UNC13C | c.437A>T p.H146L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99523826; called by muse, mutect2, varscan2
- USF3 | c.3343A>T p.N1115Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV100325883; called by muse, mutect2, varscan2
- XIRP2 | c.1594C>T p.L532F (on ENST00000628543; = p.L707F on NM_152381.6) | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs775118091, COSV99748367; called by muse, mutect2, varscan2
- ZNF383 | c.498A>T p.E166D | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100776803; called by muse, mutect2, varscan2
- ZNF7 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV100295999, COSV100296164; called by muse, mutect2
- ZNF804A | c.3053T>A p.V1018E | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV100170549; called by muse, mutect2, varscan2
- AMIGO3 | c.720_744del p.A241Tfs*33 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- APOL6 | c.281_299del p.L94Qfs*27 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- FAM131C | c.62_75del p.Q21Lfs*107 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- FCGBP | c.6643A>T p.N2215Y | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAGE2E | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LHFPL4 | c.234_247del p.G79Lfs*65 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, pindel, varscan2
- OR6C65 | c.785del p.A262Efs*7 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | called by pindel, varscan2
- RAD21 | c.1352_1374del p.L451Qfs*7 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- TRPC6 | c.694del p.Y232Mfs*64 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- ABCC8 | c.1569G>A p.E523= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100217803; called by muse, mutect2, varscan2
- ACVRL1 | c.897T>A p.A299= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV101188211; called by muse, mutect2, varscan2
- ADAMTS5 | c.189C>A p.P63= | Silent (SNP) | VAF 56/89 reads (63%) | catalogued as rs780087867, COSV99538455; called by muse, mutect2, varscan2
- ADORA1 | c.384A>T p.I128= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV99704797; called by muse, mutect2, varscan2
- BAP1 | c.948G>A p.A316= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs776898908, COSV99964591; ClinVar: likely benign; called by muse, mutect2, varscan2
- C10orf99 | c.12A>T p.L4= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100929375; called by muse, mutect2, varscan2
- CALU | c.702A>T p.R234= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV99975962; called by muse, mutect2, varscan2
- CATSPERG | c.2700C>G p.R900= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99286997; called by muse, mutect2, varscan2
- CBARP | c.978T>C p.Y326= (on ENST00000382477; = p.Y306= on NM_152769.3) | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as COSV99289962; called by muse, varscan2
- CFAP74 | c.1635G>T p.T545= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- CLIP4 | c.327T>A p.T109= | Silent (SNP) | VAF 93/135 reads (69%) | catalogued as COSV100192521; called by muse, mutect2, varscan2
- COPA | c.342T>C p.D114= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as COSV99616987; called by muse, mutect2, varscan2
- CRYBG3 | c.7245A>G p.E2415= | Silent (SNP) | VAF 150/281 reads (53%) | catalogued as COSV99477615; called by muse, mutect2, varscan2
- DIAPH3 | c.2055A>T p.T685= (on ENST00000400324 / NM_001042517.2; = p.T422= on NM_030932.3) | Silent (SNP) | VAF 177/225 reads (79%) | catalogued as COSV99934633; called by muse, mutect2, varscan2
- FBXL13 | c.711T>A p.T237= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100502236; called by muse, mutect2, varscan2
- FOXP4 | c.1962G>C p.L654= (on ENST00000307972 / NM_001012426.1; = p.L641= on NM_138457.3) | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as rs1350107458, COSV100333091; called by mutect2, varscan2
- FOXQ1 | c.621G>T p.G207= | Silent (SNP) | VAF 52/103 reads (50%) | catalogued as COSV99723364; called by muse, mutect2, varscan2
- GPX6 | c.612C>T p.V204= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100724927; called by muse, mutect2, varscan2
- HMCN1 | c.6435G>A p.L2145= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs747509922, COSV99637060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOOK2 | c.813G>A p.R271= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs371375548, COSV99317881; called by muse, mutect2, varscan2
- HUWE1 | c.6915T>C p.D2305= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99474649; called by muse, mutect2, varscan2
- IARS1 | c.3193C>T p.L1065= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV100986739; called by muse, mutect2, varscan2
- IGF2BP3 | c.507A>G p.R169= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1372334315, COSV99325956; called by muse, mutect2, varscan2
- KIAA1328 | c.1467A>C p.G489= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99695595; called by muse, mutect2, varscan2
- KRTAP10-10 | c.246G>T p.P82= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs150687639, COSV100555779; called by muse, mutect2, varscan2
- LAMC3 | c.2232T>A p.P744= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV63094363; called by muse, mutect2, varscan2
- LMOD2 | c.1392A>G p.K464= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV101505475; called by muse, mutect2, varscan2
- MAGEA1 | c.153A>T p.S51= | Silent (SNP) | VAF 84/166 reads (51%) | catalogued as COSV100756694; called by muse, mutect2
- MARK4 | c.1140A>T p.P380= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV99488976; called by muse, mutect2, varscan2
- MDH1B | c.495A>T p.I165= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100982386; called by muse, mutect2, varscan2
- NANOS3 | c.291C>A p.G97= (on ENST00000397555; = p.G116= on NM_001098622.2) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100188560; called by muse, mutect2, varscan2
- NLRP2 | c.2001T>A p.T667= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99672715; called by muse, mutect2, varscan2
- OR51G2 | c.123G>T p.L41= | Silent (SNP) | VAF 64/103 reads (62%) | catalogued as COSV100432029, COSV100432254; called by muse, mutect2, varscan2
- PALLD | c.201T>A p.I67= | Silent (SNP) | VAF 61/222 reads (27%) | catalogued as COSV99826006; called by muse, mutect2, varscan2
- PCDH15 | c.5364A>T p.T1788= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV100905877; called by muse, mutect2, varscan2
- PLXNB2 | c.2307G>C p.L769= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100834346; called by muse, mutect2, varscan2
- PSORS1C1 | c.120C>T p.H40= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs1288132906, COSV99456367; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1650C>T p.N550= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99229284; called by muse, mutect2, varscan2
- SLITRK2 | c.2118A>T p.G706= | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as rs782442564, COSV100158293; called by muse, mutect2, varscan2
- SRGAP2 | c.381A>G p.R127= | Silent (SNP) | VAF 145/502 reads (29%) | called by muse, mutect2, varscan2
- SZT2 | c.6357G>A p.L2119= (on ENST00000634258 / NM_001365999.1; = p.L2062= on NM_015284.4) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1488981993, COSV100987711; called by muse, mutect2, varscan2
- TMEM132A | c.2343T>A p.A781= (on ENST00000453848 / NM_178031.3; = p.A782= on NM_017870.4) | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV99137567; called by muse, mutect2, varscan2
- TNPO3 | c.2415A>T p.T805= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99603638; called by muse, mutect2
- TTN | c.30228A>T p.V10076= (on ENST00000591111; = p.V9149= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as COSV100633788; called by muse, mutect2, varscan2
- XIRP2 | c.2310G>A p.V770= (on ENST00000628543; = p.V945= on NM_152381.6) | Silent (SNP) | VAF 162/268 reads (60%) | catalogued as COSV99748369; called by muse, mutect2, varscan2
- ZFYVE26 | c.7305A>T p.A2435= | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as COSV100720725; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.864T>A | RNA (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- SKA2 | c.34-6404G>T | Intron (SNP) | VAF 144/174 reads (83%) | catalogued as COSV100350277; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039829 T>A | 5'Flank (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.34265-4500T>A | Intron (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
